Gene-level copy-number profile of tumor specimen ALCH-B2SD-TTP1-A from ALCHEMIST case ALCH-B2SD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.9 years (19,326 days).
Specimen ALCH-B2SD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66127b88-97d3-459b-883c-b86709f8241d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/3fa70d41-37fe-45fd-a910-f3c7ab2b24e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 14,851; copy number 2: 42,143; copy number 3: 756; copy number 4: 209; copy number 5: 859; copy number 6: 1; copy number 11: 2; copy number 17: 3.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,069,155–190,092,279, 80 genes (broad region; genes not listed).
- chr14:104,137,150–104,137,898, 1 gene: AL359399.1.
- chr17:63,477,061–63,548,977, 4 genes: ACE, AC113554.1, ACE3P, KCNH6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 865 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 5 genes, copy number 11–17: AC239859.5, RNA5SP533, AC239859.3, AC239859.2, LINC02799.
- chr2:87,311,460–87,348,728, 2 genes, copy number 5: AC068279.2, IGKV3OR2-268.
- chr3:149,369,022–198,123,232, 857 genes, copy number 5 (broad region; genes not listed).
- chr10:38,783,004–38,783,108, 1 gene, copy number 6: AL590623.1.

Autosomal genes at a single copy (total copy number 1): 11,995. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
